TCGA case TCGA-02-0266 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ca9ad9d3-0ac6-403a-98a2-f679d0ee009e

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Age at index: 14 years; Vital status: Dead; Days to death: 539 days (1.5 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 14.5 years (5,303 days); Year of diagnosis: 1990; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 15.3 years (5,596 days); Days to diagnosis: 293 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 237 days.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 293 (post initial treatment): Progression or recurrence: Yes; Days to progression: 293 days.
- Days to follow up: 539 days (1.5 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-02-0266-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.6; Shortest dimension: 0.1.
  Slide TCGA-02-0266-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 0; Percent lymphocyte infiltration: 0.
  Slide TCGA-02-0266-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 25; Percent stromal cells: 0; Percent lymphocyte infiltration: 0.
- Sample TCGA-02-0266-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 539 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 539 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 293 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-02-0266-01): tumor purity 0.84, ploidy 2.49, whole-genome doublings 1 (call status: legacy_call).
